Somatic mutation profile of tumor specimen TCGA-CJ-5671-01A (aliquot TCGA-CJ-5671-01A-11D-1534-10) from TCGA case TCGA-CJ-5671, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 51.9 years (18,954 days).
Specimen TCGA-CJ-5671-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44da2e51-6cfe-4ff7-b9a1-591700fa0cf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5671-11A (Solid Tissue Normal), aliquot TCGA-CJ-5671-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a782adf3-8501-4038-a294-3fc87c8b2820

The open-access MAF lists 68 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Frame Shift Del 5, Frame Shift Ins 1, 5'UTR 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP19 | c.958T>A p.L320M | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.625); catalogued as COSV57396472; called by muse, mutect2, varscan2
- ARHGEF35 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as COSV65313054; called by muse, mutect2, varscan2
- CAD | c.6134C>G p.A2045G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.997); catalogued as COSV53032489; called by muse, mutect2, varscan2
- CLEC10A | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54703053; called by muse, mutect2
- COL6A3 | c.9519T>A p.S3173R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55112624; called by muse, mutect2, varscan2
- CTR9 | c.1938T>G p.N646K | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV63729794; called by muse, mutect2
- CUEDC1 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV64227362; called by muse, mutect2, varscan2
- DOCK1 | c.3262A>T p.I1088L | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV54762385; called by muse, mutect2, varscan2
- FBN2 | c.6007G>A p.E2003K | Missense Mutation (SNP) | VAF 111/535 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as rs995323393, COSV52542949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIS1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.49); catalogued as COSV56191288; called by muse, mutect2
- FRY | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 63/709 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV66581292; called by muse, mutect2
- GALM | c.734A>T p.N245I | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55374335; called by muse, mutect2, varscan2
- GIT2 | c.413A>T p.H138L | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV58085637; called by muse, mutect2, varscan2
- GRIK5 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53486760; called by muse, mutect2, varscan2
- IGKV4-1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1288565275; called by muse, mutect2, varscan2
- KRTAP19-2 | c.72C>A p.C24* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV61855010, COSV61855218; called by mutect2, varscan2
- LARGE1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV61673317; called by muse, mutect2, varscan2
- MAP3K14 | c.1864T>A p.C622S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60925225; called by muse, mutect2, varscan2
- MLC1 | c.423C>T p.N141= | Splice Region (SNP) | VAF 80/390 reads (21%) | catalogued as rs121908343, CM020785, COSV61119050; called by muse, mutect2, varscan2
- NEMF | c.895T>G p.F299V | Missense Mutation (SNP) | VAF 100/867 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53595832; called by muse, varscan2
- NMNAT2 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54270152, COSV54272336; called by muse, mutect2, varscan2
- OR8U1 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 70/514 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56418846; called by muse, varscan2
- PBLD | c.266T>G p.V89G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53267480; called by muse, mutect2, varscan2
- PC | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV58994638; called by muse, mutect2, varscan2
- PER2 | c.578T>C p.F193S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54528404; called by muse, mutect2, varscan2
- POMGNT1 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | PolyPhen possibly damaging (0.76); catalogued as COSV64341108; called by muse, mutect2, varscan2
- PRTG | c.1571G>A p.S524N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66840936; called by muse, mutect2, varscan2
- RNF121 | c.244A>T p.M82L | Missense Mutation (SNP) | VAF 50/744 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62318024; called by muse, mutect2
- RTN4IP1 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 97/409 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV64806647; called by muse, mutect2, varscan2
- SETD2 | c.4885C>T p.H1629Y | Missense Mutation (SNP) | VAF 140/564 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57431577; called by muse, varscan2
- SLC33A1 | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100848316, COSV100848346; called by muse, mutect2
- SMCHD1 | c.5671T>C p.F1891L | Missense Mutation (SNP) | VAF 19/351 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55269852; called by muse, mutect2
- TEX44 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.242); catalogued as COSV58355617; called by muse, mutect2, varscan2
- TJAP1 | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52504124; called by muse, mutect2, varscan2
- TMEM63C | c.2369C>T p.S790L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs185516701; called by muse, mutect2, varscan2
- VCAN | c.7931C>T p.A2644V | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54117748; called by muse, mutect2, varscan2
- VPS26B | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1464288071, COSV55544554; called by muse, mutect2
- VPS26C | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.043); catalogued as COSV55708069; called by muse, mutect2, varscan2
- ZFY | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 204/548 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.646); catalogued as COSV50084182; called by muse, mutect2, varscan2
- ZNF175 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV51798839; called by muse, mutect2, varscan2
- ZNF570 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV57581028; called by muse, mutect2, varscan2
- ZNF770 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 72/427 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as COSV62545192; called by muse, mutect2, varscan2
- CUBN | c.10145_10146del p.R3382Kfs*3 | Frame Shift Del (DEL) | VAF 26/214 reads (12%) | called by mutect2, pindel, varscan2
- ITFG2 | c.521del p.L174Pfs*15 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- MYNN | c.576del p.Q193Rfs*12 | Frame Shift Del (DEL) | VAF 51/246 reads (21%) | called by mutect2, pindel, varscan2
- NKTR | c.1781dup p.N594Kfs*19 | Frame Shift Ins (INS) | VAF 36/149 reads (24%) | called by mutect2, pindel, varscan2
- PBRM1 | c.366_381del p.N122Kfs*47 | Frame Shift Del (DEL) | VAF 69/396 reads (17%) | called by mutect2, pindel, varscan2
- RAD52 | c.520del p.S174Hfs*2 | Frame Shift Del (DEL) | VAF 94/419 reads (22%) | called by mutect2, pindel*, varscan2
- ALDH9A1 | c.438C>A p.G146= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV61341672; called by muse, mutect2, varscan2
- ALG8 | c.1092A>G p.R364= | Silent (SNP) | VAF 29/319 reads (9%) | catalogued as COSV100220279, COSV55203354; called by muse, mutect2
- ASIC4 | c.1326C>A p.I442= (on ENST00000347842 / NM_182847.3; = p.I461= on NM_018674.6) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV61733793; called by muse, mutect2, varscan2
- DYNC2H1 | c.8955C>A p.V2985= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as COSV62108236; called by muse, mutect2, varscan2
- E2F7 | c.417G>A p.R139= | Silent (SNP) | VAF 94/451 reads (21%) | catalogued as COSV59743996; called by muse, mutect2, varscan2
- ESD | c.816C>T p.H272= | Silent (SNP) | VAF 193/1077 reads (18%) | catalogued as rs1330470722, COSV66340753; called by muse, mutect2, varscan2
- FSTL4 | c.49C>T p.L17= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV54787458; called by muse, mutect2, varscan2
- IGF1R | c.12C>T p.G4= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1215869476, COSV51400556, COSV99151450; called by muse, mutect2, varscan2
- ITCH | c.726A>G p.S242= (on ENST00000262650 / NM_001257137.3; = p.S201= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as rs1023243786, COSV52938012; called by muse, mutect2, varscan2
- KIF25 | c.891G>A p.A297= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs762853267, COSV63029164; called by muse, mutect2, varscan2
- KLHL4 | c.2145G>T p.V715= | Silent (SNP) | VAF 271/669 reads (41%) | catalogued as COSV64148545; called by muse, mutect2, varscan2
- LRIG3 | c.1464A>G p.P488= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as COSV57870715; called by muse, mutect2
- OR8U1 | c.340C>T p.L114= | Silent (SNP) | VAF 71/514 reads (14%) | catalogued as rs1565125432, COSV56418857; called by muse, varscan2
- PXDNL | c.1275C>G p.P425= | Silent (SNP) | VAF 32/234 reads (14%) | catalogued as COSV62499655; called by muse, mutect2
- SOS2 | c.3249A>T p.P1083= | Silent (SNP) | VAF 47/339 reads (14%) | catalogued as COSV53575499; called by muse, mutect2, varscan2
- THAP4 | c.1266G>T p.V422= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58710600; called by muse, mutect2, varscan2
- TXNDC16 | c.1710C>G p.T570= | Silent (SNP) | VAF 51/502 reads (10%) | catalogued as COSV55987912; called by muse, mutect2
- ZNF678 | c.498A>T p.S166= (on ENST00000343776 / NM_001367910.1; = p.S221= on NM_178549.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV59389048; called by muse, mutect2, varscan2
- ZNF707 | c.909C>T p.L303= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV62311806; called by muse, varscan2
- RNASE3 | c.-1C>T | 5'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100484305; called by muse, mutect2, varscan2
